Somatic mutation profile of tumor specimen 0DU3LO from CCDI case PBCKNI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.9 years (3,242 days).
Specimen 0DU3LO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36791b44-dbe4-43d8-9192-d692a8574942.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2865c45f-628c-4477-b3d2-4496da514680

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 192/1227 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759712763, COSV51887057; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- PNLIPRP2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 147/1027 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs782287973; called by muse, varscan2
- OSBP | c.-32T>G | 5'UTR (SNP) | VAF 112/457 reads (25%) | called by muse, varscan2
- SLC34A3 | c.-13C>T | 5'UTR (SNP) | VAF 76/493 reads (15%) | called by muse, varscan2
